Gene-level copy-number profile of tumor specimen TCGA-A5-A7WK-01A from TCGA case TCGA-A5-A7WK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.3 years (26,044 days).
Specimen TCGA-A5-A7WK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.989d3607-7b92-4edc-ae0e-946161bae5ac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A5-A7WK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4823d15-45b4-47eb-9ef6-5d826c4748b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1; copy number 2: 11,506; copy number 3: 2,765; copy number 4: 40,780; copy number 5: 432; copy number 6: 3,362; copy number 7: 141; copy number 8: 400; copy number 9: 56; copy number 10: 307; copy number 12: 26; copy number 13: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A7WK-01A-11D-A34P-01): tumor purity 0.95, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,584,530, 5 genes (within-gene range 0–2): RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 404 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,465,909–15,749,896, 18 genes, copy number 10 (within-gene range 6–10): CELA2B, CASP9, DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82.
- chr1:204,131,062–204,494,724, 15 genes, copy number 13 (within-gene range 4–13): AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B.
- chr2:113,107,214–113,643,396, 21 genes, copy number 10: IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A.
- chr3:8,733,802–8,841,808, 1 gene, copy number 9 (within-gene range 6–9): CAV3.
- chr3:8,775,402–8,963,773, 3 genes, copy number 9 (within-gene range 6–9): RAD18, AC034186.2, AC034186.1.
- chr3:9,014,123–9,104,078, 2 genes, copy number 9: SRGAP3-AS1, AC037193.1.
- chr9:127,505,339–127,696,027, 2 genes, copy number 9 (within-gene range 6–9): NIBAN2, STXBP1.
- chr10:42,185,339–42,475,349, 7 genes, copy number 12: IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1.
- chr16:11,547,722–11,828,845, 8 genes, copy number 10: LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr17:76,453,351–76,673,658, 19 genes, copy number 12: AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1.
- chr17:81,965,632–82,294,910, 24 genes, copy number 9 (within-gene range 4–9): AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN, CCDC57, AC129510.1, AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, AC132872.5, LINC01970, AC132872.1.
- chr18:2,847,006–3,478,978, 24 genes, copy number 9: EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr19:27,638,483–35,964,063, 260 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
